Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5102, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5102-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, LEFT, COMPLETE NEPHRECTOMY -

A. RENAL CELL CARCINOMA, CLEAR CELL TYPE WITH :

1. SIZE: 4.0 CM IN GREATEST DIMENSION.
2. VASCULAR AND URETERAL RESECTION MARGINS ARE FREE OF TUMOR.
3. TUMOR CONFINED BY CAPSULE.
4. FUHRMAN GRADE: III.
5. NO ANGIOLYMPHATIC INVASION PRESENT.
6. FRAGMENT OF ADRENAL GLAND WITH NO EVIDENCE OF MALIGNANCY.
7. PATHOLOGIC STAGE: T1, NX, MX.

B. UNINVOLVED KIDNEY WITH ARTERIOLONEPHROSCLEROSIS AND OLD INFARCT (0.4 CM).

Source: NCI Genomic Data Commons file f0b66909-bb3f-4643-90ca-825207180f37 (TCGA-B0-5102.528F309B-EA28-4F5D-B938-417911907CD9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).